Gene-level copy-number profile of tumor specimen TARGET-40-PAUVUL-01A from TARGET case TARGET-40-PAUVUL, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 5.5 years (2,027 days).
Specimen TARGET-40-PAUVUL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.c163a85d-4f6b-5b6a-9ef0-275763690707.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PAUVUL-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 401 have no estimate.
https://portal.gdc.cancer.gov/files/4317e633-0277-42bd-9853-c6464d43fbe9

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 520; copy number 1: 3,130; copy number 2: 10,204; copy number 3: 25,382; copy number 4: 14,911; copy number 5: 2,963; copy number 6: 468; copy number 7: 1,121; copy number 8: 1,229; copy number 9: 273; copy number 10: 14; copy number 12: 3; copy number 13: 1; copy number 31: 3.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,644 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,541,768–147,295,734, 123 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr2:101,962,056–102,179,874, 4 genes, copy number 10 (within-gene range 4–10): LINC01127, IL1R2, AC007271.1, IL1R1.
- chr4:38,366,914–38,391,675, 2 genes, copy number 8 (within-gene range 5–8): LINC02513, AC024023.1.
- chr5:58,198–2,835,139, 85 genes, copy number 7–8 (broad region; genes not listed).
- chr5:14,872,332–45,895,970, 444 genes, copy number 7–9 (broad region; genes not listed).
- chr6:44,727,921–44,830,188, 1 gene, copy number 7: AL133334.1.
- chr6:44,898,711–44,899,295, 1 gene, copy number 7: NUDT19P4.
- chr6:68,635,282–69,389,506, 1 gene, copy number 12 (within-gene range 2–12): ADGRB3.
- chr6:74,069,451–74,734,319, 5 genes, copy number 12–31 (within-gene range 2–31): AL357507.1, AL357563.1, AL356277.3, AL356277.1, AL356277.2.
- chr8:27,433,370–29,263,124, 53 genes, copy number 7–9: MIR6842, CHRNA2, EPHX2, GULOP, CLU, MIR6843, SCARA3, RNU6-1086P, AC013643.1, AC013643.3, MIR3622B, MIR3622A, AC013643.2, CCDC25, ESCO2, RNU6-1276P, PBK, AC104997.1, SCARA5, MIR4287, AC069113.1, AC069113.3, AC069113.2, NUGGC, ELP3, AC021678.1, AC021678.3, AC021678.2, RPL5P22, PNOC, ZNF395, FBXO16, AC025871.3, AC025871.2, RNU6-178P, AC025871.1, FZD3, MIR4288, RNA5SP259, EXTL3, EXTL3-AS1, INTS9, INTS9-AS1, AC040975.1, HMBOX1, Metazoa_SRP, HMBOX1-IT1, RNA5SP260, AC108449.2, KIF13B, AC108449.3, AC108449.1, HMGB1P23.
- chr8:30,279,549–31,598,204, 28 genes, copy number 7: AC090820.2, AC109329.1, PPIAP84, TUBBP1, RBPMS-AS1, RBPMS, AC102945.2, GTF2E2, AC102945.1, SMIM18, RNU5A-3P, GSR, UBXN8, HIKESHIP3, PPP2CB, TEX15, AC090281.1, AC008066.1, PURG, WRN, SUMO2P16, AC009563.1, KCTD9P6, AC068672.2, AC068672.3, AC068672.1, AC090816.1, RNA5SP261.
- chr8:34,174,886–38,601,200, 82 genes, copy number 7–9 (broad region; genes not listed).
- chr8:40,298,697–40,901,854, 5 genes, copy number 7–8 (within-gene range 1–8): SIRLNT, AC105999.1, AC010857.1, ZMAT4, AC048387.1.
- chr8:42,416,475–145,066,685, 1,577 genes, copy number 7–13 (within-gene range 4–13) (broad region; genes not listed).
- chr9:60,914,407–68,330,626, 169 genes, copy number 9 (broad region; genes not listed).
- chr9:68,353,614–68,406,500, 2 genes, copy number 9: PGM5-AS1, AL161457.2.
- chr13:75,283,503–75,807,120, 6 genes, copy number 7 (within-gene range 2–7): TBC1D4, AL139230.1, COMMD6, UCHL3, AL137782.1, LMO7-AS1.
- chr13:75,631,271–75,632,135, 1 gene, copy number 7: AL137244.1.
- chr15:100,400,395–100,828,497, 11 genes, copy number 9–10 (within-gene range 4–10): CERS3, AC027020.2, RNU6-322P, PRKXP1, AC027020.1, LINS1, RNU6-181P, ASB7, Y_RNA, AC090695.1, AC087762.1.
- chr15:101,116,603–101,933,350, 31 genes, copy number 7: AC019254.2, AC019254.1, CHSY1, SELENOS, SNRPA1, PCSK6, AC023024.1, AC023024.2, PCSK6-AS1, AC090164.2, AC090164.3, AC090164.4, SNRPCP18, AC090164.1, LINC02348, TM2D3, RNU6-807P, TARS3, AC027559.1, DNM1P47, GOLGA8VP, RN7SL209P, OR4F6, OR4F15, OR4F14P, OR4F13P, OR4F28P, WBP1LP5, AC140725.2, OR4F4, OR4G2P.
- chr19:29,811,991–30,228,715, 13 genes, copy number 7: CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1.

Autosomal genes at a single copy (total copy number 1): 1,587. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
